Somatic mutation profile of tumor specimen TARGET-10-PARIYD-09A (aliquot TARGET-10-PARIYD-09A-01D) from TARGET case TARGET-10-PARIYD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,278 days).
Specimen TARGET-10-PARIYD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6142b4dd-d1df-4329-a550-de1c319d02d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARIYD-10A (Blood Derived Normal), aliquot TARGET-10-PARIYD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/506a2d25-1bed-457f-a576-2f587614fd9e

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, Frame Shift Ins 5, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 29/57 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM33 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.116); catalogued as rs763248965, COSV100597715, COSV62933883; called by muse, mutect2, varscan2
- ASMT | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.56); catalogued as COSV101172455, COSV67109615; called by muse, mutect2, varscan2
- CUEDC2 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV50042408; called by muse, mutect2, varscan2
- EFCAB6 | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.243); catalogued as rs769219254, COSV53059472, COSV99413635; called by muse, mutect2, varscan2
- FBN2 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151329128; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN3 | c.4442G>C p.G1481A | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV54455067; called by muse, mutect2, varscan2
- GNA11 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.105); catalogued as rs777133920, COSV50017708; called by muse, mutect2, varscan2
- IL7R | c.728dup p.T244Nfs*26 | Frame Shift Ins (INS) | VAF 59/132 reads (45%) | catalogued as COSV57406244, COSV57406538, COSV57408312, COSV57408637, COSV57411199, COSV57411469, COSV57413100, COSV99073420; called by mutect2, pindel*, varscan2*
- NOTCH1 | c.4775T>C p.F1592S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024854, COSV53033159; called by muse, mutect2, varscan2
- PHF6 | c.129_130insTCTA p.K44Sfs*16 | Frame Shift Ins (INS) | VAF 64/66 reads (97%) | catalogued as COSV59699971, COSV59700160, COSV59706640; called by mutect2, pindel, varscan2
- PPP1R26 | c.2716C>T p.R906* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as rs1391369461, COSV63354911; called by muse, mutect2, varscan2
- WT1 | c.1091_1092insCTATCCC p.T365Yfs*10 | Frame Shift Ins (INS) | VAF 12/31 reads (39%) | catalogued as COSV100187393, COSV60065578, COSV60066574, COSV60067966, COSV60069180, COSV60069294, COSV60069675, COSV60071329, COSV60072717, COSV60072799, COSV60073173, COSV60073318, COSV60074036, COSV60082207, COSV60083929, COSV…; called by pindel, varscan2
- DNM2 | c.2333dup p.G779Wfs*45 (on ENST00000355667 / NM_001005360.3; = p.G775Wfs*45 on NM_004945.3) | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | called by mutect2, pindel
- NOTCH1 | c.6598_6599insCTATCCCCCCCTAT p.V2200Afs*53 | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | called by mutect2, pindel
- WT1 | c.1069_1085delinsTG p.R357_V362delins* | Nonsense Mutation (DEL) | VAF 13/22 reads (59%) | called by pindel, varscan2*
- DNAH5 | c.6735C>A p.V2245= | Silent (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- LRRC4C | c.1410G>A p.R470= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as rs780905572, COSV53422029; called by muse, mutect2, varscan2
- MAGI1 | c.288C>G p.A96= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV100442721, COSV58336682; called by muse, mutect2, varscan2
- OR11A1 | c.198G>A p.A66= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as rs755635499; called by muse, mutect2, varscan2
- TOP3B | c.1497C>T p.L499= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as rs1310359325, COSV64117520; called by muse, mutect2, varscan2
- PDCD6IPP1 | n.337A>G | RNA (SNP) | VAF 90/177 reads (51%) | called by muse, mutect2, varscan2
